Somatic mutation profile of tumor specimen TCGA-BA-A6DD-01A (aliquot TCGA-BA-A6DD-01A-12D-A31L-08) from TCGA case TCGA-BA-A6DD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 44.9 years (16,401 days).
Specimen TCGA-BA-A6DD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51a1bf29-3358-4bb3-ad69-39ba1ab3104f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DD-10A (Blood Derived Normal), aliquot TCGA-BA-A6DD-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/776676c3-d7f5-4ebe-b640-62663fb3b1ba

The open-access MAF lists 58 somatic variants for this specimen: 47 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 9, Splice Site 3, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>A p.X153_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- LCE1F | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV57669605; called by muse, mutect2, varscan2
- MMAB | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376128990, CM023191; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.1599G>T p.R533S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100584466; called by muse, mutect2, varscan2
- ACOT12 | c.908T>A p.I303N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100297112; called by muse, mutect2
- BARD1 | c.1613G>T p.S538I | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99639615; called by muse, mutect2
- BDKRB2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as rs368495707; called by muse, mutect2, varscan2
- C6orf89 | c.211A>T p.I71F (on ENST00000373685; = p.I78F on NM_152734.4) | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV100769766; called by muse, mutect2, varscan2
- CACNA1E | c.2731C>T p.R911W | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs370013304, COSV62390334; called by muse, mutect2
- CD40LG | c.648A>C p.K216N | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV101033537; called by muse, mutect2, varscan2
- CENATAC | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100548884; called by muse, mutect2, varscan2
- CHRNG | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs777663481, COSV101264017; called by muse, mutect2
- DHX33 | c.1916G>C p.G639A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99834488; called by muse, mutect2, varscan2
- FZD1 | c.1249T>G p.S417A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV99842686; called by muse, mutect2, varscan2
- GCOM1 | c.347A>T p.K116M | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.661); catalogued as COSV99985225; called by muse, mutect2, varscan2
- GRIN2A | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100410744; called by muse, mutect2, varscan2
- GUSB | c.1838G>C p.R613T | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100512735; called by muse, mutect2, varscan2
- HAUS6 | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261920568, COSV100998158; called by muse, mutect2, varscan2
- KATNIP | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs763806971, COSV99851780; called by muse, mutect2, varscan2
- KCNH7 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as rs746778116, COSV100037341; called by muse, mutect2, varscan2
- LARP1B | c.1301A>C p.N434T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV99218782; called by muse, mutect2, varscan2
- LRRC43 | c.1238A>T p.E413V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV100336901; called by muse, mutect2, varscan2
- MMP15 | c.280G>C p.V94L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV99539681; called by muse, mutect2
- MUC16 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as COSV101201045; called by muse, mutect2
- MYO1B | c.1502A>G p.N501S | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as rs199738105; called by muse, mutect2
- MYO9A | c.6707C>G p.T2236S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as COSV100614141; called by muse, mutect2
- NCOA3 | c.218A>T p.K73M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100508041; called by muse, mutect2, varscan2
- OR10K2 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149624; called by muse, mutect2
- OR4K5 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV60004549, COSV60004807; called by muse, mutect2
- PCDHGB1 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV53975285; called by muse, mutect2, varscan2
- PCDHGC5 | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99341857; called by muse, mutect2
- PGM5 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs200812025; called by muse, mutect2
- PHF3 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV100013806; called by muse, mutect2, varscan2
- RECK | c.195T>G p.H65Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as COSV100937601; called by muse, mutect2, varscan2
- SHOC1 | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV100597963; called by muse, mutect2, varscan2
- STAR | c.178+1G>A p.X60_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as CS115085, COSV52418585; called by muse, mutect2, varscan2
- STRA6 | c.1478T>A p.V493D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.261); catalogued as COSV100121246; called by muse, mutect2, varscan2
- STRADB | c.315+2T>A p.X105_splice | Splice Site (SNP) | VAF 11/91 reads (12%) | catalogued as COSV99524737; called by muse, mutect2, varscan2
- TGOLN2 | c.1201A>G p.I401V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as COSV99965107; called by muse, mutect2, varscan2
- TIAM1 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs146528832; called by muse, mutect2, varscan2
- TMEM94 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV100050797; called by muse, mutect2
- TXNDC9 | c.280T>A p.C94S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99959996; called by muse, mutect2, varscan2
- YIPF7 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747220881, COSV60656011; called by muse, mutect2, varscan2
- ZNF367 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757111205, COSV64546835; called by muse, mutect2, varscan2
- TRGV2 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZNF84 | c.262A>G p.M88V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTRL | c.4008A>G p.K1336= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as COSV99443411; called by muse, mutect2
- LRRC45 | c.825G>A p.K275= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as COSV100141930; called by muse, mutect2, varscan2
- MCOLN3 | c.307C>T p.L103= | Silent (SNP) | VAF 4/81 reads (5%) | catalogued as COSV100352927; called by muse, mutect2
- MTMR14 | c.192G>T p.L64= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as COSV99931511; called by muse, mutect2, varscan2
- MYLK | c.1503C>A p.T501= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100659260; called by muse, mutect2, varscan2
- NEUROG2 | c.51A>G p.L17= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100511945; called by muse, mutect2, varscan2
- SGF29 | c.123C>T p.T41= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV57683479; called by muse, mutect2, varscan2
- SNRNP200 | c.3468G>A p.L1156= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as COSV100107979; called by muse, mutect2, varscan2
- TRIM38 | c.954C>T p.Y318= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100837629; called by muse, mutect2, varscan2
- AL163540.1 | n.165A>G | RNA (SNP) | VAF 33/308 reads (11%) | called by muse, mutect2, varscan2
- TRIM61 | c.526-2388T>C | Intron (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100256197; called by muse, mutect2, varscan2
